Somatic mutation profile of tumor specimen MMRF_1710_1_BM_CD138pos (aliquot MMRF_1710_1_BM_CD138pos_T1_KBS5U_L05547) from MMRF case MMRF_1710, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.3 years (17,639 days).
Specimen MMRF_1710_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad679716-8d8f-44b6-987e-bfd4c2728aec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1710_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1710_1_PB_Whole_C3_KBS5U_L05567; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dd5941e-6f3e-4eff-b2c5-d9a681c15f2e

The open-access MAF lists 114 somatic variants for this specimen: 41 protein-altering or splice-affecting, 15 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 33, Missense Mutation 28, Silent 15, Intron 14, 3'Flank 6, Nonsense Mutation 4, Frame Shift Del 4, Splice Site 4, 5'UTR 3, 5'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC141 | c.2688T>G p.S896R | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs183526282; called by muse, mutect2, varscan2
- CDH11 | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99219443; called by muse, mutect2, varscan2
- COL22A1 | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as rs1240412760, COSV57335361; called by muse, mutect2
- DLG5 | c.2383-1G>T p.X795_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as rs772201520, COSV64949080; called by muse, mutect2, varscan2
- FOXRED2 | c.1625-1G>T p.X542_splice | Splice Site (SNP) | VAF 13/57 reads (23%) | catalogued as COSV53400646; called by muse, mutect2
- GUCD1 | c.47A>T p.D16V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV101238107; called by muse, mutect2, varscan2
- H3C12 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as rs766949103, COSV58152382; called by muse, mutect2, varscan2
- IGLV3-1 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs137930227; called by muse, varscan2
- IGLV4-60 | c.154T>A p.Y52N | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as rs377758528; called by muse, mutect2, varscan2
- IGLV4-60 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs757582575; called by muse, varscan2
- LYN | c.1138_1139del p.M380Vfs*10 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as rs1457545626; called by mutect2, pindel, varscan2
- MUC4 | c.2801C>A p.T934K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.413); catalogued as rs376569443; called by muse, mutect2, varscan2
- NDUFV1 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 17/140 reads (12%) | catalogued as CM106159; called by muse, mutect2, varscan2
- TEX11 | c.1330C>A p.L444M (on ENST00000344304; = p.L429M on NM_031276.3) | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60234578; called by muse, mutect2
- TMBIM6 | c.554T>A p.V185D | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57279441; called by muse, mutect2, varscan2
- TRDN | c.1421-1G>T p.X474_splice | Splice Site (SNP) | VAF 11/58 reads (19%) | catalogued as COSV62121968; called by muse, mutect2, varscan2
- ZNF432 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | catalogued as rs770363541, COSV55418136; called by muse, mutect2, varscan2
- ABCC10 | c.2756C>G p.S919C (on ENST00000372530 / NM_001198934.2; = p.S891C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ACOXL | c.1466T>G p.L489* (on ENST00000389811 / NM_001371254.1; = p.L459* on NM_001142807.4) | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- ADGRV1 | c.9879del p.W3294Gfs*11 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- APP | c.1351C>G p.Q451E | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ATP6V1A | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CLVS2 | c.46del p.A16Lfs*19 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- IGHJ5 | c.39_48del p.T14Tfs*? | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by pindel, varscan2
- IL22RA1 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- IL31RA | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ITGA7 | c.1762A>G p.T588A (on ENST00000555728; = p.T544A on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- JTB | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); called by muse, mutect2
- KANK1 | c.3547G>A p.D1183N | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- METAP2 | c.867+2T>G p.X289_splice | Splice Site (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- MTOR | c.934C>G p.H312D | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PKD1L1 | c.8347G>C p.E2783Q | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- PREP | c.689A>C p.E230A (on ENST00000369110; = p.E296A on NM_002726.5) | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- RBP3 | c.3526C>G p.Q1176E | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- RTN2 | c.1299C>G p.H433Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SBF1 | c.3247C>A p.Q1083K | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.033); called by muse, mutect2
- SHANK1 | c.4432A>G p.R1478G | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFE3 | c.1667C>A p.S556Y | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TRAP1 | c.339A>G p.I113M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ZNF257 | c.515C>A p.T172N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZZZ3 | c.1466A>C p.Y489S | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ACP7 | c.1080G>A p.P360= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs368033628; called by muse, mutect2
- ALDH18A1 | c.1855T>C p.L619= | Silent (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- EPN2 | c.18C>T p.I6= | Silent (SNP) | VAF 53/199 reads (27%) | catalogued as COSV59063807; called by muse, mutect2, varscan2
- FNBP4 | c.1011A>G p.E337= | Silent (SNP) | VAF 82/259 reads (32%) | catalogued as rs1460251113; called by muse, mutect2, varscan2
- IGLV1-51 | c.66G>C p.V22= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs549938250; called by muse, varscan2
- IGLV4-60 | c.252T>C p.P84= | Silent (SNP) | VAF 52/192 reads (27%) | catalogued as rs781513896; called by muse, varscan2
- KCND3 | c.93G>A p.P31= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs978360186; called by muse, mutect2, varscan2
- KIF13B | c.3375C>T p.D1125= | Silent (SNP) | VAF 40/121 reads (33%) | called by muse, mutect2, varscan2
- MADCAM1 | c.597G>T p.P199= | Silent (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- PPIP5K2 | c.2019G>A p.L673= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs1424883989; called by muse, mutect2, varscan2
- SIAH1 | c.33C>T p.T11= | Silent (SNP) | VAF 94/368 reads (26%) | catalogued as rs571226258, COSV63211122; called by muse, mutect2, varscan2
- SPTBN2 | c.2370G>T p.R790= | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- TNPO2 | c.708C>T p.A236= | Silent (SNP) | VAF 45/176 reads (26%) | catalogued as COSV100790417; called by muse, mutect2, varscan2
- UBAP2 | c.1641C>T p.L547= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as rs780070478; called by muse, mutect2, varscan2
- ZNF500 | c.243G>A p.P81= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs759010509; called by muse, mutect2, varscan2
- AGL | c.*2290G>T | 3'UTR (SNP) | VAF 40/135 reads (30%) | called by muse, mutect2, varscan2
- AL662899.2 | c.367+261C>T | Intron (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- AMOT | c.*866C>A | 3'UTR (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- AP000812.4 | c.*1715C>A | 3'UTR (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- ARHGEF6 | c.*809A>T | 3'UTR (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- ATP7B | c.*830G>A | 3'UTR (SNP) | VAF 52/104 reads (50%) | called by muse, mutect2, varscan2
- C1QTNF7 | c.*3108G>T | 3'UTR (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- C2orf88 | c.*1913G>C | 3'UTR (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- C3orf70 | c.*2506C>T | 3'UTR (SNP) | VAF 39/170 reads (23%) | called by muse, mutect2, varscan2
- CBX5 | c.*8454G>C | 3'UTR (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2
- CDC14B | chr9:96496259 G>A | 3'Flank (SNP) | VAF 42/188 reads (22%) | catalogued as rs776527067; called by muse, mutect2, varscan2
- CDHR1 | c.*1233C>A | 3'UTR (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- CHIT1 | c.915+73C>T | Intron (SNP) | VAF 11/58 reads (19%) | catalogued as rs1017588576; called by muse, mutect2, varscan2
- COA1 | c.-38-587C>T | Intron (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- COL4A1 | c.*597G>T | 3'UTR (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- CPTP | c.*634G>A | 3'UTR (SNP) | VAF 38/145 reads (26%) | called by muse, mutect2, varscan2
- F3 | c.*1216A>T | 3'UTR (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- FHL1 | c.*689C>T | 3'UTR (SNP) | VAF 24/129 reads (19%) | catalogued as rs1355490388; called by muse, mutect2, varscan2
- FXR1 | chr3:180912537 del T | 5'Flank (DEL) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- GASK1A | c.*146+29T>C | Intron (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- HLCS | chr21:36749062 T>G | 3'Flank (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- JUN | c.*839A>C | 3'UTR (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- KAZN | c.*2263G>A | 3'UTR (SNP) | VAF 40/129 reads (31%) | called by muse, mutect2, varscan2
- KIT | c.*1193A>C | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- KRTAP19-1 | c.*98T>A | 3'UTR (SNP) | VAF 83/311 reads (27%) | called by muse, mutect2, varscan2
- LRTOMT | c.438-81C>G | Intron (SNP) | VAF 12/324 reads (4%) | called by muse, mutect2
- MRPS27 | c.694+194C>T | Intron (SNP) | VAF 11/51 reads (22%) | catalogued as rs539074042; called by muse, mutect2, varscan2
- NAMPT | c.*1983A>T | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- NAMPT | c.1089+38_1089+41del | Intron (DEL) | VAF 14/109 reads (13%) | called by mutect2, pindel, varscan2
- NCAM2 | c.*2610G>A | 3'UTR (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- NLRP14 | c.*128A>T | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- NPR2 | c.-245A>C | 5'UTR (SNP) | VAF 19/118 reads (16%) | catalogued as rs1381012526, COSV61312879; called by muse, mutect2
- NPR3 | c.769+4231G>T | Intron (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- OR51A4 | chr11:4943941 A>G | 3'Flank (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- OSBP2 | c.1108-5631G>A | Intron (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- PHF24 | c.*608A>T | 3'UTR (SNP) | VAF 13/74 reads (18%) | catalogued as rs1282761318; called by muse, mutect2, varscan2
- PLEKHJ1 | chr19:2230204 T>A | 3'Flank (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2, varscan2
- PPP1R12C | c.322-122A>G | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- PRRX1 | c.599+66A>G | Intron (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- PTBP3 | chr9:112220104 G>A | 3'Flank (SNP) | VAF 87/207 reads (42%) | called by muse, mutect2, varscan2
- REEP5 | c.*1798del | 3'UTR (DEL) | VAF 18/112 reads (16%) | called by mutect2, pindel, varscan2
- RMDN1 | chr8:86468515 G>T | 3'Flank (SNP) | VAF 117/382 reads (31%) | catalogued as rs750622621; called by muse, mutect2, varscan2
- SGIP1 | c.*1035del | 3'UTR (DEL) | VAF 26/110 reads (24%) | catalogued as rs575082820; called by mutect2, varscan2
- SHH | c.*1957C>T | 3'UTR (SNP) | VAF 47/137 reads (34%) | catalogued as rs113576797; called by muse, mutect2, varscan2
- SHROOM4 | c.*997+1287G>T | Intron (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.*1322T>A | 3'UTR (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- SPESP1 | c.-5C>T | 5'UTR (SNP) | VAF 68/236 reads (29%) | catalogued as rs748683191, COSV52987036; called by muse, mutect2, varscan2
- SPRED1 | c.*206T>C | 3'UTR (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- SUPT3H | c.*323G>T | 3'UTR (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- SUSD5 | c.*155C>G | 3'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- TRIP4 | chr15:64387788 G>A | 5'Flank (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- UBE2D3 | c.-336-210G>T | Intron (SNP) | VAF 43/147 reads (29%) | called by muse, mutect2, varscan2
- VPS37A | c.-80G>C | 5'UTR (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- VPS37B | c.*1012T>C | 3'UTR (SNP) | VAF 38/137 reads (28%) | called by muse, mutect2, varscan2
- XRRA1 | c.*8C>A | 3'UTR (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- ZC3H11A | c.299-34T>A | Intron (SNP) | VAF 47/172 reads (27%) | called by muse, mutect2, varscan2
- ZFP1 | c.*221C>G | 3'UTR (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- ZRANB3 | c.*745C>T | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
